ALCHEMIST case ALCH-B2VH — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/d7eeed04-7c06-4204-87bc-192f880f3df7

Demographics
Sex at birth: male.

Diagnoses (1)
1. Large cell carcinoma, NOS: Age at diagnosis: 70.1 years (25,605 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-B2VH-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-B2VH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B2VH-TTP1-A-1-0-S2: Section location: Top; Percent tumor cells: 67; Percent tumor nuclei: 86; Percent normal cells: 11; Percent necrosis: 20; Percent stromal cells: 2; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
